Somatic mutation profile of tumor specimen MMRF_1497_1_BM_CD138pos (aliquot MMRF_1497_1_BM_CD138pos_T1_KBS5U_L02844) from MMRF case MMRF_1497, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.0 years (22,296 days).
Specimen MMRF_1497_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 635a3a37-b9ea-4a6c-ba07-f6cf9edcbdfb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1497_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1497_1_PB_Whole_C3_KBS5U_L02856; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fd7539b-b4a7-440e-bd10-d822ca58e5da

The open-access MAF lists 106 somatic variants for this specimen: 35 protein-altering or splice-affecting, 14 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 31, Missense Mutation 29, Intron 17, Silent 14, 5'UTR 5, Nonsense Mutation 5, RNA 2, 5'Flank 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- APOBR | c.1915G>A p.E639K (on ENST00000431282; = p.E648K on NM_018690.4) | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.56); PolyPhen benign (0.084); catalogued as COSV60489623; called by muse, mutect2, varscan2
- H2BC8 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV55126798; called by muse, mutect2, varscan2
- IGHV1-69 | c.338A>T p.Y113F | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as rs536685284; called by muse, varscan2
- IGHV1-69 | c.224G>C p.G75A | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs564335126; called by muse, varscan2
- IGHV2-70 | c.171G>A p.W57* | Nonsense Mutation (SNP) | VAF 22/22 reads (100%) | catalogued as rs370713802; called by muse, varscan2
- IGLV4-69 | c.182A>G p.E61G | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760215553; called by muse, varscan2
- IGLV4-69 | c.270C>G p.S90R | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as rs538650616; called by muse, varscan2
- KXD1 | c.373G>C p.A125P | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs1228005477; called by muse, mutect2, varscan2
- LZTS3 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.679); catalogued as rs760609930; called by muse, mutect2, varscan2
- PIM1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV100998571, COSV104423821, COSV65164906; called by muse, mutect2, varscan2
- PRRX2 | c.483G>T p.R161S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100991207, COSV100991223; called by muse, mutect2, varscan2
- STAG2 | c.3395T>G p.L1132* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV54365553; called by muse, mutect2
- AC025287.4 | c.186T>G p.D62E | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANLN | c.2288T>A p.L763H | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ART3 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- CCAR1 | c.1377T>G p.D459E | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDH12 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 82/187 reads (44%) | called by muse, mutect2, varscan2
- CENPE | c.5579G>C p.S1860T | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- FAT2 | c.7983C>G p.I2661M | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2
- GBF1 | c.5563C>A p.P1855T (on ENST00000369983 / NM_001377137.1; = p.P1854T on NM_004193.3) | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.017); called by muse, mutect2
- IGHMBP2 | c.1232A>G p.H411R | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- IGLC2 | c.254A>T p.Y85F | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); called by muse, varscan2
- IGLV4-69 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.063); called by muse, varscan2
- IGLV5-52 | c.361A>G p.N121D | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, varscan2
- MAP3K4 | c.3433C>A p.H1145N | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- MGAT5 | c.2077C>T p.P693S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NKAIN2 | c.34T>C p.F12L | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PRKD2 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RIMBP2 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- RNF19A | c.2456C>G p.T819R | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEC62 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 20/268 reads (7%) | called by muse, mutect2
- TOM1L2 | c.913T>G p.F305V (on ENST00000379504 / NM_001350333.2; = p.F255V on NM_001033551.3) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, varscan2
- TRAF3 | c.151_154del p.Y51Sfs*30 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel
- ZNF469 | c.3578T>G p.F1193C (on ENST00000437464; = p.F1221C on NM_001367624.2) | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2
- ACTL9 | c.894G>A p.P298= | Silent (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- ATP5F1A | c.948A>G p.K316= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs772480203, COSV56360099; called by muse, mutect2, varscan2
- CACNA1I | c.2118C>T p.I706= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs778202719; called by muse, mutect2, varscan2
- HEATR1 | c.2520C>T p.A840= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs984913969; called by muse, mutect2, varscan2
- IGHV2-70D | c.246A>C p.T82= | Silent (SNP) | VAF 20/63 reads (32%) | called by muse, varscan2
- IGLV4-60 | c.216A>G p.E72= | Silent (SNP) | VAF 36/69 reads (52%) | catalogued as rs369851306; called by muse, mutect2, varscan2
- OR51A4 | c.177G>A p.E59= | Silent (SNP) | VAF 30/303 reads (10%) | catalogued as COSV100985237; called by muse, mutect2
- PNMA1 | c.177A>G p.E59= | Silent (SNP) | VAF 22/24 reads (92%) | called by muse, mutect2, varscan2
- SALL4 | c.2259C>T p.S753= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs369158623, COSV99409794; called by muse, mutect2, varscan2
- SREBF1 | c.2082C>T p.N694= | Silent (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- SYN2 | c.792C>T p.F264= | Silent (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- TNC | c.4272T>C p.Y1424= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs371580892; called by muse, mutect2
- TNS4 | c.1992C>T p.Y664= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs780731629; called by muse, mutect2, varscan2
- TRIM38 | c.859T>C p.L287= | Silent (SNP) | VAF 6/11 reads (55%) | called by muse, varscan2
- ABCE1 | c.1263+64C>T | Intron (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- AFF1 | c.*3445A>C | 3'UTR (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- AP4B1 | c.1511-23G>C | Intron (SNP) | VAF 41/129 reads (32%) | called by muse, mutect2, varscan2
- ATP6V1C1 | c.*800A>G | 3'UTR (SNP) | VAF 10/28 reads (36%) | catalogued as rs190953200; called by muse, mutect2, varscan2
- BAHD1 | c.*1196G>C | 3'UTR (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021388 A>T | 5'Flank (SNP) | VAF 27/57 reads (47%) | called by muse, mutect2, varscan2
- BTG1 | c.*987C>T | 3'UTR (SNP) | VAF 42/80 reads (53%) | called by muse, mutect2, varscan2
- BTK | c.1632-33A>T | Intron (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- CALN1 | c.*2612C>T | 3'UTR (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- CCDC91 | c.*338A>G | 3'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- CLDN3 | c.-127C>T | 5'UTR (SNP) | VAF 4/52 reads (8%) | catalogued as rs1401694250; called by muse, mutect2
- COL4A3 | c.144+88A>C | Intron (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- CPT1B | c.-19-21A>G | Intron (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- DBX1 | c.*35G>A | 3'UTR (SNP) | VAF 21/119 reads (18%) | called by muse, mutect2, varscan2
- DCHS2 | n.8625T>A | RNA (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- DGKQ | c.*824C>T | 3'UTR (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- EGLN1 | c.*1182del | 3'UTR (DEL) | VAF 12/43 reads (28%) | catalogued as rs1362327359; called by mutect2, pindel, varscan2
- FAH | c.*90G>A | 3'UTR (SNP) | VAF 8/71 reads (11%) | catalogued as rs1042085003, COSV99930547; called by muse, mutect2, varscan2
- FBXO45 | c.*1413A>G | 3'UTR (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- FOXP2 | c.1267-1489A>G | Intron (SNP) | VAF 31/89 reads (35%) | catalogued as rs778277593; called by muse, mutect2, varscan2
- GATAD2A | c.*2558G>T | 3'UTR (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- GPR35 | c.-23A>G | 5'UTR (SNP) | VAF 5/39 reads (13%) | catalogued as COSV54384503; called by muse, mutect2, varscan2
- GRB14 | c.*320C>T | 3'UTR (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- IKZF5 | c.*787A>G | 3'UTR (SNP) | VAF 8/73 reads (11%) | catalogued as rs1405275754; called by muse, mutect2, varscan2
- KCND1 | c.1122-798_1122-797del | Intron (DEL) | VAF 13/24 reads (54%) | called by pindel, varscan2
- KIAA1549 | c.*775T>C | 3'UTR (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- LINC01567 | n.191C>G | RNA (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- LRRC28 | c.*1856A>G | 3'UTR (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2, varscan2
- MICU2 | c.598-1225G>A | Intron (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- MRPS27 | c.694+310C>G | Intron (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- MYCN | c.*205C>T | 3'UTR (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- MYH15 | c.*68T>G | 3'UTR (SNP) | VAF 11/216 reads (5%) | called by muse, mutect2
- NALCN | c.*299T>C | 3'UTR (SNP) | VAF 14/24 reads (58%) | called by muse, mutect2, varscan2
- P2RX5 | c.*421T>C | 3'UTR (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- PARVG | c.80-103G>A | Intron (SNP) | VAF 7/9 reads (78%) | called by muse, mutect2, varscan2
- PAX6 | c.142-442G>T | Intron (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- PAX6 | c.142-443T>G | Intron (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- PCK2 | c.*10C>G | 3'UTR (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
- PEBP1 | chr12:118135879 C>T | 5'Flank (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- PECR | c.*654A>C | 3'UTR (SNP) | VAF 5/12 reads (42%) | catalogued as rs1010982244; called by muse, mutect2, varscan2
- PNKD | c.*177G>A | 3'UTR (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- PRKAA1 | c.*328A>G | 3'UTR (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2, varscan2
- PRR9 | c.*213A>C | 3'UTR (SNP) | VAF 14/67 reads (21%) | called by muse, mutect2, varscan2
- PSMC2 | c.290+28dup | Intron (INS) | VAF 12/87 reads (14%) | catalogued as rs1320408938; called by mutect2, pindel, varscan2
- RABGAP1L | c.*552T>A | 3'UTR (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- RBFOX3 | c.569-204G>A | Intron (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- RNF32 | c.*60G>A | 3'UTR (SNP) | VAF 5/18 reads (28%) | called by mutect2, varscan2
- ROGDI | c.*136G>T | 3'UTR (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- ROR1 | c.1174+724_1174+725insG | Intron (INS) | VAF 8/80 reads (10%) | catalogued as rs1186368480; called by mutect2, pindel
- RSL24D1 | c.*416A>G | 3'UTR (SNP) | VAF 17/371 reads (5%) | catalogued as rs1011369805; called by muse, mutect2
- SOX4 | c.*2630del | 3'UTR (DEL) | VAF 21/49 reads (43%) | called by mutect2, pindel, varscan2
- SSR3 | c.*500A>G | 3'UTR (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- STXBP5 | c.917+1122T>A | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
- TMEM196 | c.-704A>G | 5'UTR (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- VSTM1 | c.-79G>A | 5'UTR (SNP) | VAF 13/50 reads (26%) | catalogued as rs1327025512; called by muse, mutect2, varscan2
- VXN | c.127-122T>A | Intron (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- ZBED9 | c.-225T>C | 5'UTR (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
